Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DE, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DE-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Thymoma, type B2, malignant
8584/3
Site: Mediastinum, anterior C38.1
J20 6/13/14

Surgical Pathology Report

* Procedure/Addenda present *

Taken:

DOB:

Gender: F

Specimen Received:

Anterior mediastinal mass and thymus

Addendum Report

Addendum Diagnosis

A representative portion of this case is sent for specialized laboratory testing. This addendum is created to report that the results are scanned into the patient's electronic medical record

TEST/ASSAY

RESULTS

Thymoma Class = 1

Patients with a Class1 molecular signature have a low risk of experiencing near term (within 10 years) clinical metastasis.

Addendum Comment

A section or paraffin block from the patient's thymoma tissue was sent for
- Thymoma(tm) Gene Expression Assay

Type of Specimen: FFPE prepared tumor tissue

THYMOMA GENE EXPRESSION ASSAY DESCRIPTION

THYMOMA<174> gene expression assay for thymoma tumors is a proprietary assay which uses RT-PCR to determine the expression levels of a 23 gene panel (4 controls) in primary tumor tissue samples. The THYMOMA<174> classification is calculated from the gene expression results as compared to results of a training set of patients with known outcomes.

Final Pathologic Diagnosis:

Thymus, thymectomy:

[page 2 of 2]
Encapsulated thymoma, Type B2 (1.7 cm in greatest dimension) with microcyst formation.

Seven benign lymph nodes (0/7).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received in a single formalin filled container labeled with the patient's name, and additionally labeled as "anterior mediastinal mass and thymus" and consists of two unoriented separate fragments of lobulated fibroadipose soft tissue; the larger fragment measures 14.5 x 7 x 1.2 cm and the smaller fragment measures 3.5 x 3.5 x 0.5 cm. The total weight of the specimen is 60 grams. The larger fragment is partially surfaced by purple-gray membranous covering. The external surface is inked in black. Step sectioning through the larger fragment reveals a 1.7 x 1.2 x 1.2 cm well circumscribed, homogeneous, yellow-tan, firm nodule that immediately abuts one aspect of the inked external surface. The remaining cut surface of this fragment is homogeneous, lobulated soft yellow-tan and fatty. The external surface of the smaller fragment is inked in red. Step sectioning through this fragment reveals a homogeneous lobulated, fibrofatty. No lesions are identified within this smaller fragment. Three potential lymph nodes are identified, ranging from 0.4 cm to 0.5 cm in greatest dimension.

Representative sections, with the nodule in its entirety, are submitted as follows:

- 1-2 well circumscribed nodule;
- 3-4 well circumscribed nodule with relationship to closest inked surface, paired sections;
- 5 well circumscribed nodule;
- 6-11 larger fragment;
- 12-13 smaller fragment;
- 14 Potential whole lymph nodes.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Source: NCI Genomic Data Commons file 99aefcad-4455-46d9-a26c-19af2a54543f (TCGA-X7-A8DE.71A610B1-DA62-4B47-80DD-E32644D10D9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).